Surgical pathology report (de-identified scan), TCGA case TCGA-KQ-A41Q, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Cornell Medical College, specimen TCGA-KQ-A41Q-01A (Primary Tumor).

[page 1 of 2]
urgical Pathology Laboratory

cal Pathology Report

In Lab Date:

Report Date:

Submitted by:

Reviewed Initials	Date Reviewed: 7/16/12	

Telephone:

Location:

CLINICAL INFORMATION:

Bladder cancer. Robotic radical cystectomy, ileo-conduit diversion.

Specimen submitted: A. Bladder; B. Left lymph nodes; C. Right lymph nodes; D. Left distal ureter; E. Right distal ureter

DIAGNOSIS:

A. Bladder and prostate (excision):

Invasive urothelial carcinoma, high grade.

The carcinoma invades through the muscularis propria into the perivesical fat.

Lymphovascular invasion is not identified.

All surgical resection margins are negative for carcinoma.

Carcinoma in-situ is identified.

The remaining bladder shows chronic inflammation and focal biopsy site changes.

Two lymph nodes, negative for metastatic carcinoma (0/2).

TNM: T3b, N0, MX

Prostatic adenocarcinoma, Gleason score 3+4=7.

The tumor involves the right lobe and is organ confined.

Lymphovascular and perineural invasion are not identified.

Seminal vesicles and all surgical margins are negative for tumor.

Seminal vesicles show amyloid deposition (confirmed with congo red stain).

TNM: T2a, N0, MX

B. Lymph nodes, left (excision):

Eleven lymph nodes, negative for metastatic carcinoma (0/11).

C. Lymph nodes, right (excision):

Fifteen lymph nodes, negative for metastatic carcinoma (0/15).

D. Ureter, left distal (excision):

Benign segment of ureter with chronic inflammation.

E. Ureter, right distal (excision):

Benign segment of ureter with chronic inflammation.

GROSS DESCRIPTION:

A. Received fresh, the specimen is labeled "bladder," and consists of a 24.0 x 16.0 x 6.0 cm specimen which includes a 9.0 x 8.0 x 5.5 cm bladder, a 5.0 x 3.5 x 3.0 cm prostate, a 1.5 x 0.7 cm right ureter, and 1.0 x 0.5 cm left ureter. The right seminal vesicle

[page 2 of 2]
measures 4.0 x 1.2 x 0.9 cm and the left seminal vesicle measures 4.5 x 1.5 x 0.8 cm. The right vas deferens measures 13.0 x 0.4 cm and the left vas deferens measures 14.5 x 0.5 cm. The perivesical fat is inked green. The right side of the prostate is inked green and the left side black. On cut section, there is a 7.0 x 5.5 cm fungating necrotic mass with raised edematous borders involving the right anterior and lateral walls and grossly invading the perivesicle fat. The remainder of the bladder is trabeculated with multiple diverticula. There is a bladder neck polypoid mass measuring 0.7 x 0.5 x 0.4 cm. The prostate and is serially sectioned and shows grossly unremarkable cut surfaces. Representative sections are submitted. Summary of sections: A1-right ureter margin; A2-left ureter margin; A3-urethral margin; A4 through A13-representative tumor; A14-anterior bladder; A15-posterior bladder; A16-left bladder; A17-right bladder; A18-trigone; A19 and A22-possible lymph nodes; A23-LA prostate; A24-RA prostate; A25-LAC prostate; A26-LPC prostate; A27-RC prostate; A28-LAE prostate; A29-LPE prostate; A30-RAE prostate; A31-RPE prostate; A32-LG prostate; A33-LG prostate; A34-RG prostate; A36-RG prostate; A37-left seminal vesicle; A38-right seminal vesicle.

B. Received fresh, the specimen is labeled "left lymph nodes," and consists of a 7.0 x 5.0 x 1.0 cm aggregate of lymph nodes and fatty tissue. The specimen is submitted entirely. Summary of sections: B1 and B2-one node bisected; B3-bisected; B4-bisected; B5 to B9-remaining tissue.

C. Received fresh, the specimen is labeled "right lymph nodes," and consists of a 7.2 x 5.5 x 1.0 cm aggregate of tissue containing lymph nodes. The specimen is submitted entirely. Summary of sections: C1 and C2-one lymph node bisected; C3 and C4-one lymph node; C5-10-remaining tissue.

D. Received fresh, the specimen is labeled "left distal ureter," and consists of a 1.2 cm long by 0.7 cm diameter ureter with a clip and stitch. The specimen is submitted entirely. Summary of sections: D1.

E. Received fresh, the specimen is labeled "right distal ureter," and consists of a 1.5 cm long by 1.0 cm in diameter ureter with clip and stitch and a 1.0 x 1.0 x 0.4 cm fragment of attached fatty tissue. The specimen is submitted entirely. Summary of sections: E1.
(

***** Electronically Signed Out *****

Attending Pathologist

The attending pathologist whose signature appears on this report has reviewed the diagnostic slides, and has edited the gross and microscopic portions of the report in rendering the final diagnosis.

Slides: A-41, B-9, C-10, D-1, E-1

Source: NCI Genomic Data Commons file d2f4718d-f8c8-4608-bd57-9ec4f7ae11fe (TCGA-KQ-A41Q.5047D01C-1425-4EE5-BB6F-5DD484C9E030.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).